Somatic mutation profile of tumor specimen ALCH-B058-TTP1-A (aliquot ALCH-B058-TTP1-A-2-0-D-A709-36) from ALCHEMIST case ALCH-B058, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.4 years (27,914 days).
Specimen ALCH-B058-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 902c7b32-b459-4e2f-83b3-e0cfec138af7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B058-NB1-A (Blood Derived Normal), aliquot ALCH-B058-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecef630b-86d9-4e99-8ae0-d8643de5de6d

The open-access MAF lists 161 somatic variants for this specimen: 103 protein-altering or splice-affecting, 40 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 40, Nonsense Mutation 8, 3'UTR 7, Intron 5, Splice Site 3, RNA 3, 5'UTR 2, Frame Shift Del 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 40/123 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC104389.6 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV57964511; called by muse, mutect2, varscan2
- AICDA | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 53/418 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV99984430; called by muse, mutect2, varscan2
- CDKL2 | c.324T>A p.F108L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs548637556; called by muse, mutect2, varscan2
- CFAP47 | c.5386G>A p.A1796T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV57976401; called by muse, mutect2, varscan2
- CHRM3 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV55104143; called by muse, mutect2, varscan2
- DGKI | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55944316; called by muse, mutect2, varscan2
- DNAH5 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200494845, COSV54206361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100519354; called by muse, mutect2
- ERBB4 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1226469223; called by muse, mutect2, varscan2
- EYS | c.5037G>T p.M1679I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs761298139, COSV58201928; called by mutect2, varscan2
- FGF10 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 20/145 reads (14%) | catalogued as COSV52939619; called by muse, mutect2, varscan2
- GJA4 | c.304del p.R102Efs*29 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as COSV100654620, COSV60726000; called by mutect2, pindel, varscan2
- GRIN2B | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.233); catalogued as rs796052580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXD13 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs774419506, COSV101184277, COSV101184371; called by muse, mutect2, varscan2
- HOXD8 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57486367; called by mutect2, varscan2
- HTR1E | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375047597; called by muse, mutect2, varscan2
- KCNT2 | c.3297A>G p.V1099= | Splice Region (SNP) | VAF 14/233 reads (6%) | catalogued as rs1478425660, COSV54114405; called by muse, mutect2
- KMT2D | c.6241G>T p.E2081* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV56470880, COSV56478035; called by muse, varscan2
- MUC17 | c.3142C>A p.P1048T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60293319; called by muse, mutect2, varscan2
- MYF5 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV57356767; called by muse, mutect2, varscan2
- NCBP1 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs77021424; called by muse, mutect2
- NCOA1 | c.2935A>G p.T979A | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs747050033; called by muse, mutect2, varscan2
- PCDHA7 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.37); catalogued as COSV100971542; called by muse, mutect2, varscan2
- R3HDM2 | c.1063A>T p.I355F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs201843316; called by muse, mutect2, varscan2
- RABL6 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61037567; called by muse, mutect2, varscan2
- RALBP1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 40/244 reads (16%) | catalogued as COSV99070003, COSV99191974; called by muse, mutect2, varscan2
- SCN8A | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100634014; called by muse, mutect2, varscan2
- SLC9A2 | c.1966C>G p.R656G | Missense Mutation (SNP) | VAF 84/431 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as rs992622109; called by muse, mutect2, varscan2
- SMG1 | c.5944C>T p.Q1982* | Nonsense Mutation (SNP) | VAF 27/184 reads (15%) | catalogued as COSV67172850; called by muse, mutect2, varscan2
- TIPARP | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 69/384 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99070342; called by muse, mutect2, varscan2
- TTN | c.13237C>T p.R4413W (on ENST00000591111; = p.R4367W on NM_003319.4) | Missense Mutation (SNP) | VAF 34/218 reads (16%) | PolyPhen possibly damaging (0.9); catalogued as rs749719834; called by muse, mutect2, varscan2
- UNC5D | c.955G>C p.V319L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV54802501; called by mutect2, varscan2
- WDR31 | c.485G>T p.C162F (on ENST00000374193 / NM_001006615.3; = p.C161F on NM_145241.5) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.565); catalogued as COSV59145651; called by muse, mutect2
- WDR72 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs758148753; called by muse, mutect2, varscan2
- ZFP91 | c.1420G>C p.D474H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV60160101; called by muse, mutect2, varscan2
- ADD1 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADK | c.337G>T p.G113W (on ENST00000286621; = p.G96W on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AFG3L2 | c.235A>T p.N79Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ANKRD11 | c.4710G>C p.E1570D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- BCL9 | c.3950G>A p.R1317K | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- C9orf43 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CABIN1 | c.2514G>T p.K838N | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.38); called by muse, mutect2
- CCDC168 | c.15743G>C p.C5248S | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.098); called by muse, mutect2
- CCDC189 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CDC14A | c.977+1G>C p.X326_splice | Splice Site (SNP) | VAF 42/229 reads (18%) | called by muse, mutect2, varscan2
- CDC14C | c.686A>G p.Y229C (on ENST00000428251; = p.Y122C on NM_152627.3) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CDC40 | c.1354G>T p.D452Y | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CDV3 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CEP63 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- CIP2A | c.1562A>G p.N521S | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- COL17A1 | c.4007C>T p.P1336L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL25A1 | c.778A>C p.K260Q | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCLK1 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- DMD | c.6305C>A p.S2102Y | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DNAH5 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- ERCC3 | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- F2R | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GABRG1 | c.320T>A p.M107K | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- GALNT5 | c.2692A>G p.I898V | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- GNAZ | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GRIN1 | c.576G>C p.E192D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRM1 | c.2366T>A p.F789Y | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IST1 | c.1096G>C p.D366H (on ENST00000535424 / NM_001270976.1; = p.L351F on NM_014761.4) | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ITGAM | c.1823G>T p.G608V (on ENST00000648685 / NM_001145808.2; = p.G607V on NM_000632.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCND3 | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, varscan2
- KIDINS220 | c.5269T>A p.S1757T | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); called by mutect2, varscan2
- MEP1B | c.6T>A p.D2E | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2
- MPST | c.586C>T p.P196S (on ENST00000341116 / NM_001369904.2; = p.P216S on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NEDD4L | c.2548-2A>G p.X850_splice (on ENST00000400345 / NM_001144967.3; = p.X830_splice on NM_015277.6) | Splice Site (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
- NIPBL | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP8 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NR4A3 | c.1600T>A p.L534I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2
- OR5K3 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 28/185 reads (15%) | called by muse, mutect2, varscan2
- OR6V1 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR8B4 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); called by muse, mutect2
- OXCT1 | c.1236C>G p.N412K | Missense Mutation (SNP) | VAF 9/343 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OXCT1 | c.1235A>T p.N412I | Missense Mutation (SNP) | VAF 9/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZD7 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRSS41 | c.629-1G>C p.X210_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- PTPN4 | c.224C>G p.A75G | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RAB32 | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RARG | c.1000A>G p.I334V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RARS2 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2
- SLC52A3 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC52A3 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, varscan2
- SMARCAL1 | c.1711G>T p.V571F | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STOX2 | c.913A>T p.T305S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SUSD4 | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SYCE1 | c.845T>A p.L282Q (on ENST00000343131 / NM_001143764.3; = p.L246Q on NM_130784.3) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF7L | c.211G>C p.A71P | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- TDRD15 | c.5390G>T p.W1797L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- TMEFF2 | c.495C>A p.C165* | Nonsense Mutation (SNP) | VAF 65/410 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.76721G>A p.G25574D (on ENST00000591111; = p.G18150D on NM_003319.4) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TTN | c.61153T>A p.Y20385N (on ENST00000591111; = p.Y12961N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | PolyPhen probably damaging (0.998); called by muse, varscan2
- TTN | c.27574A>T p.N9192Y (on ENST00000591111; = p.N8265Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- UNC80 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- USH2A | c.8390C>G p.S2797* | Nonsense Mutation (SNP) | VAF 51/204 reads (25%) | called by muse, mutect2, varscan2
- USP13 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- VEGFC | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- YTHDC1 | c.992A>T p.E331V | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ZDHHC13 | c.997T>A p.L333M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ZNF507 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS20 | c.5052A>G p.K1684= | Silent (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- AL592490.1 | c.313C>T p.L105= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- AMTN | c.453A>T p.G151= | Silent (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.4149G>A p.P1383= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs774177266; called by muse, mutect2, varscan2
- ARL14 | c.156C>A p.I52= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs776701439, COSV100296450, COSV57900579; called by muse, mutect2, varscan2
- BCL9 | c.3117C>A p.S1039= | Silent (SNP) | VAF 19/195 reads (10%) | called by muse, mutect2
- CASP4 | c.579C>T p.T193= | Silent (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- CCDC114 | c.792G>T p.V264= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- CCDC28B | c.537C>A p.L179= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- CFTR | c.2874A>G p.Q958= | Silent (SNP) | VAF 29/316 reads (9%) | catalogued as rs1423987631; called by muse, mutect2
- DARS2 | c.1497G>A p.S499= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as rs201884983; ClinVar: likely benign; called by muse, mutect2
- DIRAS1 | c.378G>A p.T126= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV60215105; called by muse, mutect2, varscan2
- GRM8 | c.1656C>T p.S552= | Silent (SNP) | VAF 27/193 reads (14%) | called by muse, mutect2, varscan2
- ITIH5 | c.1692C>T p.G564= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs771293155; called by muse, mutect2, varscan2
- ITPR3 | c.796C>A p.R266= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100967605; called by muse, mutect2, varscan2
- KCNH7 | c.2292C>A p.T764= | Silent (SNP) | VAF 30/443 reads (7%) | called by muse, mutect2
- KCNK10 | c.465C>A p.G155= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- LMOD2 | c.690C>A p.T230= | Silent (SNP) | VAF 38/211 reads (18%) | called by muse, mutect2, varscan2
- MAML2 | c.2736T>C p.P912= | Silent (SNP) | VAF 46/197 reads (23%) | catalogued as rs1363808897; called by muse, mutect2, varscan2
- MAML2 | c.573A>G p.R191= | Silent (SNP) | VAF 34/141 reads (24%) | called by muse, mutect2, varscan2
- MOCS1 | c.690G>T p.L230= | Silent (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- MYO3B | c.2781G>A p.K927= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- NLRP8 | c.1185C>A p.V395= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- NR4A3 | c.108C>A p.T36= | Silent (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- OR2Y1 | c.615C>T p.V205= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs752095483, COSV57136101; called by muse, mutect2, varscan2
- OR4K13 | c.726T>A p.A242= | Silent (SNP) | VAF 103/287 reads (36%) | called by muse, mutect2, varscan2
- OR5I1 | c.792C>G p.P264= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.675G>T p.T225= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV53901307; called by muse, mutect2, varscan2
- PCLO | c.2376C>A p.T792= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs750085293; called by muse, mutect2, varscan2
- PIEZO1 | c.3048C>T p.T1016= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- PLXNC1 | c.2241C>G p.S747= | Silent (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- RIT2 | c.459A>G p.Q153= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as rs142876352; called by muse, mutect2, varscan2
- SLC52A3 | c.360C>T p.C120= | Silent (SNP) | VAF 56/204 reads (27%) | called by muse, varscan2
- TAS2R42 | c.441G>A p.V147= | Silent (SNP) | VAF 15/76 reads (20%) | called by muse, varscan2
- TENM1 | c.465T>C p.S155= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs750343501; called by muse, mutect2, varscan2
- TRAV5 | c.153C>A p.T51= | Silent (SNP) | VAF 84/244 reads (34%) | called by muse, mutect2, varscan2
- TRHDE | c.1830T>C p.N610= | Silent (SNP) | VAF 14/207 reads (7%) | called by muse, mutect2
- TRPM6 | c.1572A>G p.A524= | Silent (SNP) | VAF 41/374 reads (11%) | called by muse, mutect2, varscan2
- TULP1 | c.549T>C p.N183= | Silent (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- VPS13A | c.5529T>A p.I1843= | Silent (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2
- AC136628.2 | n.921G>T | RNA (SNP) | VAF 4/54 reads (7%) | catalogued as rs986039416; called by muse, varscan2
- AGT | c.*5A>T | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2
- ARHGEF4 | c.-466A>G | 5'UTR (SNP) | VAF 18/84 reads (21%) | catalogued as rs1479143349; called by muse, mutect2, varscan2
- CDKN2A | c.151-39C>T | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as COSV58691252; called by mutect2, varscan2
- CLCA4 | c.1467+14T>A | Intron (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- FGF2 | c.*20T>A | 3'UTR (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2
- FGF2 | c.*21C>A | 3'UTR (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2
- GRM3 | c.*21C>A | 3'UTR (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+245G>A | Intron (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2
- IRAK3 | c.*42C>A | 3'UTR (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- NAPA | c.561+195C>T | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, varscan2
- NBPF22P | n.568T>A | RNA (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- NEU1 | c.353-33T>G | Intron (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- NF1 | chr17:31379256 A>G | 3'Flank (SNP) | VAF 4/17 reads (24%) | catalogued as rs1180741305; called by muse, mutect2, varscan2
- OR51F5P | n.344C>T | RNA (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- PCK2 | c.-87C>G | 5'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, varscan2
- PLEKHG5 | c.*29G>A | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*717G>C | 3'UTR (SNP) | VAF 18/379 reads (5%) | called by muse, mutect2
